Somatic mutation profile of tumor specimen TARGET-10-PAPESB-09A (aliquot TARGET-10-PAPESB-09A-01D) from TARGET case TARGET-10-PAPESB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,535 days).
Specimen TARGET-10-PAPESB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28fdac3b-db5e-4b51-bd2d-3ebe6700b4c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPESB-14A (Bone Marrow Normal), aliquot TARGET-10-PAPESB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3dac1afb-a125-4224-9207-7a1160ddbc58

The open-access MAF lists 56 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 9, Intron 6, Nonsense Mutation 3, 5'Flank 1, RNA 1, Splice Site 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.3602C>T p.S1201L | Missense Mutation (SNP) | VAF 85/229 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.772); catalogued as COSV56855134; called by muse, mutect2, varscan2
- ABCD2 | c.444C>G p.I148M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1414028696; called by muse, mutect2, varscan2
- AGGF1 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs749202307; called by muse, mutect2, varscan2
- ALDH9A1 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773816744, COSV61340368; called by muse, mutect2, varscan2
- ALG10 | c.1336G>C p.V446L | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV56791508; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); catalogued as rs749528030, COSV100598574, COSV63049029; called by muse, mutect2, varscan2
- HTR1B | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV64051728; called by muse, mutect2
- HUNK | c.1032C>A p.S344R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV99528713; called by muse, mutect2
- IL17B | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs778900330, COSV55783725; called by muse, mutect2, varscan2
- MFSD14A | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1315992652; called by muse, mutect2, varscan2
- MUC17 | c.818G>C p.G273A | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV100072132; called by muse, mutect2
- OR2B3 | c.335G>T p.C112F | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as rs758195482; called by muse, mutect2
- TDRD6 | c.1518G>C p.L506F | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60177225; called by muse, mutect2, varscan2
- TRIM3 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.067); catalogued as rs987479453; called by muse, mutect2, varscan2
- ZNF607 | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 29/99 reads (29%) | catalogued as rs376038316; called by muse, mutect2, varscan2
- ANKRD44 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP11A | c.2258C>A p.A753E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.024); called by muse, mutect2
- BAZ2A | c.775G>T p.V259L | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2
- COL11A2 | c.3047C>T p.S1016F (on ENST00000341947 / NM_080680.3; = p.S909F on NM_080679.2) | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DBX1 | c.153dup p.A52Rfs*196 | Frame Shift Ins (INS) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- DCBLD2 | c.2083C>T p.Q695* | Nonsense Mutation (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- DYNAP | c.541G>C p.A181P (on ENST00000321600; = p.A155P on NM_173629.3) | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GRAMD1B | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- HUWE1 | c.9431G>T p.R3144L | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2
- KY | c.1542G>T p.Q514H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- MYEF2 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2
- MYT1 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PCDH15 | c.3823G>A p.V1275I | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- PLCE1 | c.1538C>G p.S513* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- POGLUT2 | c.1085A>T p.H362L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RIOX1 | c.1140C>A p.D380E | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- SEC31A | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SEMA5B | c.3332G>A p.R1111K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SNTG1 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TAS2R39 | c.212C>A p.T71K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); called by muse, mutect2
- USP20 | c.1541C>A p.A514D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.197); called by muse, mutect2
- XPO5 | c.1011+1G>T p.X337_splice | Splice Site (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- ZNF658 | c.2759C>T p.S920F | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- EIF2AK3 | c.483C>G p.L161= | Silent (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2
- KRTAP17-1 | c.276G>T p.G92= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- MUC17 | c.1980G>C p.V660= | Silent (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- MYT1 | c.324G>A p.S108= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs200184375, COSV60501826; called by muse, mutect2, varscan2
- PODNL1 | c.471C>T p.T157= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs202144687; called by muse, varscan2
- RIC8B | c.249G>C p.V83= | Silent (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- SPRY3 | c.739C>T p.L247= | Silent (SNP) | VAF 52/150 reads (35%) | catalogued as COSV57143083; called by muse, mutect2
- TMEM132A | c.1740C>T p.L580= (on ENST00000453848 / NM_178031.3; = p.L581= on NM_017870.4) | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs528088514, COSV50000678; called by muse, mutect2, varscan2
- TRHR | c.936C>T p.N312= | Silent (SNP) | VAF 65/264 reads (25%) | called by muse, mutect2, varscan2
- CCDC78 | c.561-32G>A | Intron (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- CENPW | c.126+43G>C | Intron (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- DCHS2 | n.6743C>G | RNA (SNP) | VAF 44/141 reads (31%) | called by muse, mutect2, varscan2
- IMPDH2 | chr3:49029403 C>G | 5'Flank (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- NOX4 | c.57+238G>A | Intron (SNP) | VAF 25/60 reads (42%) | catalogued as rs577710229; called by muse, mutect2
- PAQR5 | c.513-73C>A | Intron (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- TGIF1 | c.-81_-80insGGGTTC | 5'UTR (INS) | VAF 26/90 reads (29%) | called by mutect2, pindel, varscan2
- TMEM154 | c.365-2538G>A | Intron (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2, varscan2
- ZNF211 | c.218-670C>A | Intron (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
